CPTAC case C3L-06023 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/acd5a8b2-d94f-4bcc-9b28-9c865ac2c38c

Demographics
Sex at birth: female; Race: white; Year of birth: 1951; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 67.8 years (24,752 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIC; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,777 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,777 days (4.9 years); Clark level: III; Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 3 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 340 days; Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 621 days (1.7 years); Disease response: Tumor Free.
- Days to follow up: 964 days (2.6 years); Disease response: Tumor Free; ECOG performance status: 0.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 26.3; Cigarettes per day: 15; Tobacco smoking onset year: 1983; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 39.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06023-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 390 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-06023-22: Section location: Extremities; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-06023-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -9 days; Method of sample procurement: Blood Draw.
